Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAO7, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAO7-01A (Primary Tumor).

[page 1 of 2]
ICD O.3

Seminoma NOS 90613
Site (L) Testis NOS C42.9
9/30/21/14

Acct#:

Ord #=
SURGICAL PATH

SIGNED

Perform D/T=

(1 of 1)

Specimen Source: L TESTICLE
CASE NO.:
GROSS EXAM DATE:
PHYSICIAN & PAGER #:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA (10cm) WITH AREAS OF NECROSIS, left testis, procedure not stated. (See note)
2. LYMPHOVASCULAR INVASION CANNOT BE RULED OUT. (See note)
3. NO INVASION OF EPIDIDYMIS NOTED.
4. TUMOR LIMITED TO TESTIS.
5. MARGINS FREE OF TUMOR.
6. INTRATUBULAR GERM CELL NEOPLASIA, EXTENSIVE.
7. pT1NXMX
8. TESTICULAR TISSUE WITH EVIDENCE OF SPERMATOGENESIS.

Note: Although the clusters of malignant cells seen in lymphovascular spaces are likely to represent carry-over artifact the possibility of vascular invasion at these sites cannot be completely ruled out. Tumor cells positive for PLAP and cKit and negative for CD30.

GROSS DESCRIPTION:

[page 2 of 2]
Name:

Loc:

SURGICAL PATH

(Continued)

Acct#:

The specimen is received in one part, unfixed, labeled with the patient's name, and "left testicle." The specimen consists of a 60 gram orchiectomy specimen that includes a 6 x 4.5 x 3 cm testis, a 1.5 x 1 x 0.5 cm epididymis and a spermatic cord that measures 8.5 cm in length and 2 cm in maximum diameter. Directly adjacent to the base of the epididymis and the directly adjacent to the tunica albuginea, there is a white-tan, fleshy, homogenous mass that measures 4 x 2 x 2 cm. Directly adjacent to this mass, there is a second mass that is tan-yellow and hemorrhagic with cystic necrosis, that measures 3.5 x 2 x 2 cm. The epididymis and tunica albuginea are both smooth and unremarkable in appearance. The rim of testicular parenchyma adjacent to the tumor is somewhat compressed but is otherwise grossly unremarkable. There are no palpable masses in the spermatic cord. On cut section, the spermatic cord consists of vas deferens, arteries and veins. It appears otherwise unremarkable. Representative sections are submitted as follows:

- Cassettes #1 and #2 - white-tan tumor.
- Cassettes #3 and #4 - necrotic tumor.
- Cassette #5 - epididymis and tumor.
- Cassette #6 - normal testes and tumor.
- Cassette #7 - spermatic cord at the resection margin.
- Cassette #8 - spermatic cord at mid-section.
- Cassette #9 - spermatic cord, peritesticular.

Source: NCI Genomic Data Commons file 1d4160e2-e052-427d-bda3-0a16c5d431ad (TCGA-XE-AAO7-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).